Somatic mutation profile of tumor specimen TCGA-E7-A6MD-01A (aliquot TCGA-E7-A6MD-01A-41D-A34U-08) from TCGA case TCGA-E7-A6MD, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Anterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 66.2 years (24,180 days).
Specimen TCGA-E7-A6MD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43e97830-e610-4be1-b11c-d035f9042a22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-E7-A6MD-10B (Blood Derived Normal), aliquot TCGA-E7-A6MD-10B-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bb7d697d-7ca4-4dc4-9377-de4318618d7d

The open-access MAF lists 514 somatic variants for this specimen: 374 protein-altering or splice-affecting, 132 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 325, Silent 132, Nonsense Mutation 34, Splice Region 5, Intron 4, Frame Shift Del 4, Splice Site 4, RNA 2, 5'UTR 1, Frame Shift Ins 1, Nonstop Mutation 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL2 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 25/116 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55452713, COSV55455449; called by muse, mutect2, varscan2
- KDM6A | c.3879-2A>T p.X1293_splice | Splice Site (SNP) | VAF 41/63 reads (65%) | hotspot (GDC flag); catalogued as COSV65039916; called by muse, mutect2, varscan2
- ABCA4 | c.101C>G p.S34C | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV64678136; called by muse, mutect2, varscan2
- ABCB8 | c.2072G>T p.G691V (on ENST00000297504 / NM_001282291.2; = p.G674V on NM_007188.5) | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52510398; called by muse, mutect2, varscan2
- ABCD2 | c.1058G>A p.S353N | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58055294; called by muse, mutect2, varscan2
- ACAN | c.7267G>A p.E2423K (on ENST00000560601 / NM_001369268.1; = p.E2347K on NM_001135.3) | Missense Mutation (SNP) | VAF 7/113 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs1477219599, COSV61369593; called by muse, mutect2
- ACSF3 | c.141C>G p.F47L | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.17); catalogued as COSV58081824; called by muse, varscan2
- ACTL6A | c.49G>C p.D17H | Missense Mutation (SNP) | VAF 24/134 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66999481; called by muse, mutect2, varscan2
- ADAM10 | c.301C>G p.H101D | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.937); catalogued as COSV53054876; called by muse, mutect2, varscan2
- ADAMTS2 | c.2751-1G>T p.X917_splice | Splice Site (SNP) | VAF 19/131 reads (15%) | catalogued as COSV52393671; called by muse, mutect2, varscan2
- ADCK5 | c.257G>C p.R86P | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.461); catalogued as COSV100450739, COSV58235130; called by muse, mutect2, varscan2
- ADGRG4 | c.5978C>G p.S1993C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54966777; called by muse, mutect2, varscan2
- ADORA3 | c.916T>C p.S306P | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV53986871; called by muse, mutect2, varscan2
- AEN | c.493C>T p.R165W | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.135); catalogued as rs1203174947, COSV60430438; called by muse, mutect2, varscan2
- AFDN | c.2423C>T p.S808L | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.275); catalogued as rs139174764; called by muse, mutect2, varscan2
- AFG1L | c.1300G>C p.D434H | Missense Mutation (SNP) | VAF 48/92 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV64558343; called by muse, mutect2, varscan2
- AGO1 | c.1398G>A p.K466= | Splice Region (SNP) | VAF 37/87 reads (43%) | catalogued as COSV64596558; called by muse, mutect2, varscan2
- AKNA | c.4228G>A p.E1410K | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as rs781060930, COSV56339410; called by muse, mutect2, varscan2
- AKR7A2 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52516917; called by muse, mutect2, varscan2
- ALDH16A1 | c.284C>G p.A95G | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV53196726; called by muse, mutect2, varscan2
- ALPK3 | c.782C>G p.S261* | Nonsense Mutation (SNP) | VAF 9/37 reads (24%) | catalogued as COSV99362060; called by muse, mutect2, varscan2
- ALS2CL | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as COSV59670800; called by muse, mutect2, varscan2
- AMOTL2 | c.2278C>G p.L760V (on ENST00000422605; = p.L761V on NM_016201.4) | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.079); catalogued as COSV51440933, COSV99850631; called by muse, mutect2, varscan2
- ANGPTL2 | c.1302G>C p.Q434H | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT tolerated (0.56); PolyPhen benign (0.075); catalogued as COSV52232786; called by muse, mutect2, varscan2
- ANKRD11 | c.3779C>T p.S1260L | Missense Mutation (SNP) | VAF 32/148 reads (22%) | SIFT tolerated, low confidence (0.84); PolyPhen benign (0); catalogued as COSV56372025; called by muse, mutect2, varscan2
- ANKRD55 | c.1691G>A p.R564Q | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.992); catalogued as rs756382232, COSV61950788; called by muse, mutect2, varscan2
- APP | c.1623G>A p.M541I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.332); catalogued as COSV61002716; called by mutect2, varscan2
- AQP4 | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67219461; called by muse, mutect2, varscan2
- ARHGAP31 | c.285C>G p.C95W | Missense Mutation (SNP) | VAF 33/113 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51799054; called by muse, mutect2, varscan2
- ARHGEF10L | c.2851C>T p.R951W | Missense Mutation (SNP) | VAF 28/60 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs781534515, COSV51440634; called by muse, mutect2, varscan2
- ARSG | c.907A>G p.N303D | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as COSV71593994; called by muse, mutect2, varscan2
- ARTN | c.566G>A p.R189Q (on ENST00000372354; = p.R197Q on NM_057090.2) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64912022; called by muse, mutect2, varscan2
- ASH1L | c.1504C>T p.Q502* | Nonsense Mutation (SNP) | VAF 55/150 reads (37%) | catalogued as COSV100853612, COSV64208415; called by muse, mutect2, varscan2
- ATAD1 | c.312A>T p.K104N | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV57758740; called by muse, mutect2, varscan2
- ATF2 | c.277G>C p.E93Q | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV51375567; called by muse, mutect2, varscan2
- ATG4B | c.1108+5G>C | Splice Region (SNP) | VAF 12/32 reads (38%) | catalogued as COSV59872026; called by muse, mutect2, varscan2
- ATP6V1A | c.1758C>G p.F586L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV56364721; called by muse, mutect2, varscan2
- ATP8B1 | c.3668C>T p.S1223F | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV99377921; called by muse, mutect2
- AXIN2 | c.1156G>C p.E386Q | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.098); catalogued as rs1173549577, COSV100195885, COSV61061159; called by muse, mutect2
- B4GALNT3 | c.2584C>T p.Q862* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV56755096, COSV99843644; called by muse, mutect2, varscan2
- BACE2 | c.1393G>A p.E465K | Missense Mutation (SNP) | VAF 18/93 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.509); catalogued as rs1035187431, COSV100160799, COSV57743781; called by muse, mutect2, varscan2
- BAZ2B | c.6107G>C p.R2036T | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV58602482, COSV58609982; called by muse, mutect2
- BCAM | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1201261411, COSV54304939; called by muse, varscan2
- BCL9 | c.3796C>T p.P1266S | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0.06); catalogued as COSV52344309; called by muse, mutect2, varscan2
- BFSP2 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.674); catalogued as COSV56591992; called by muse, mutect2, varscan2
- BNC2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs746370194, COSV66157419; called by muse, mutect2, varscan2
- BRCA2 | c.5722C>G p.L1908V | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as CD951626, COSV66462314; called by muse, mutect2, varscan2
- BTAF1 | c.3679C>G p.P1227A | Missense Mutation (SNP) | VAF 26/204 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1564713380, COSV56439475; called by muse, mutect2, varscan2
- C10orf90 | c.508G>C p.E170Q | Missense Mutation (SNP) | VAF 50/161 reads (31%) | SIFT tolerated (0.84); PolyPhen benign (0.007); catalogued as COSV52960893, COSV52964183; called by muse, mutect2, varscan2
- C11orf24 | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.138); catalogued as COSV58506588; called by muse, mutect2, varscan2
- C12orf54 | c.178G>C p.D60H | Missense Mutation (SNP) | VAF 29/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV58361066; called by muse, mutect2, varscan2
- C1orf112 | c.1835T>A p.L612* | Nonsense Mutation (SNP) | VAF 14/77 reads (18%) | catalogued as rs1307765347, COSV53682549; called by muse, mutect2, varscan2
- C1orf198 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as rs749135657, COSV64175387; called by muse, mutect2, varscan2
- C3orf20 | c.820G>C p.E274Q | Missense Mutation (SNP) | VAF 175/376 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.056); catalogued as COSV53788427, COSV53789370; called by muse, mutect2, varscan2
- CACNA2D1 | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.182); catalogued as rs375189396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG2 | c.397A>T p.N133Y | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55641182; called by muse, mutect2, varscan2
- CADPS | c.2232C>G p.I744M | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV51868659, COSV51903037; called by muse, mutect2, varscan2
- CADPS | c.503C>T p.T168I | Missense Mutation (SNP) | VAF 61/174 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.991); catalogued as COSV51903058; called by muse, mutect2, varscan2
- CAMK2D | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.347); catalogued as COSV56439166; called by muse, mutect2, varscan2
- CASKIN2 | c.1945G>A p.E649K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs772690752, COSV58594884; called by muse, mutect2, varscan2
- CASP4 | c.679G>A p.D227N | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV67744887; called by muse, mutect2, varscan2
- CASQ1 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.434); catalogued as COSV63624553; called by muse, mutect2, varscan2
- CCDC88A | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 9/75 reads (12%) | catalogued as COSV99711245; called by muse, mutect2, varscan2
- CCDC88B | c.1675G>C p.E559Q | Missense Mutation (SNP) | VAF 43/116 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.343); catalogued as rs139020637; called by muse, mutect2, varscan2
- CCNB1 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV56511032; called by muse, mutect2, varscan2
- CD86 | c.632C>T p.T211M (on ENST00000330540 / NM_175862.5; = p.T205M on NM_006889.4) | Missense Mutation (SNP) | VAF 121/430 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.387); catalogued as rs776283945, COSV52610300; called by muse, mutect2, varscan2
- CDH23 | c.4465G>C p.E1489Q | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV56490181; called by muse, mutect2, varscan2
- CDH3 | c.1981G>A p.G661R | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV50571790, COSV50572361; called by muse, mutect2, varscan2
- CDHR2 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV56145236; called by muse, mutect2, varscan2
- CELSR2 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs764686331, COSV54770033; called by muse, mutect2, varscan2
- CEP290 | c.6184C>T p.Q2062* | Nonsense Mutation (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100469957; called by muse, mutect2, varscan2
- CEP68 | c.574C>G p.Q192E | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as COSV53127554; called by muse, mutect2, varscan2
- CHEK2 | c.1015G>T p.D339Y (on ENST00000382580 / NM_001005735.2; = p.D296Y on NM_007194.4) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs876659553, COSV100102551, COSV60425907, COSV60427990; ClinVar: uncertain significance; called by muse, mutect2
- CIITA | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 13/87 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV60862109; called by muse, mutect2, varscan2
- CLASP1 | c.1382G>C p.R461T | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55340500; called by muse, mutect2, varscan2
- CLDN15 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated (0.44); PolyPhen benign (0.015); catalogued as rs1027266090, COSV57658726; called by muse, mutect2, varscan2
- CLIC4 | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1482409024, COSV65527677; called by muse, mutect2, varscan2
- CMYA5 | c.11137C>T p.Q3713* | Nonsense Mutation (SNP) | VAF 26/68 reads (38%) | catalogued as COSV101484398; called by muse, mutect2, varscan2
- CNOT6L | c.970G>C p.D324H (on ENST00000504123 / NM_001286790.2; = p.D319H on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53701409, COSV53703400; called by muse, mutect2, varscan2
- CNTNAP4 | c.880C>T p.H294Y | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1340109243, COSV56697192, COSV56700419; called by muse, mutect2, varscan2
- CNTNAP5 | c.2842G>T p.V948F | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.232); catalogued as COSV70512308; called by muse, mutect2, varscan2
- COBLL1 | c.3346G>C p.D1116H (on ENST00000392717; = p.D1078H on NM_014900.5) | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV52074871; called by muse, mutect2, varscan2
- COL17A1 | c.4054G>C p.E1352Q | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.135); catalogued as COSV59825096, COSV59829155; called by muse, mutect2, varscan2
- COLGALT2 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0.173); catalogued as rs749692817, COSV62731325; called by muse, mutect2, varscan2
- CSNK2A1 | c.523G>C p.D175H | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV53937708; called by muse, mutect2, varscan2
- DAPK1 | c.1276G>C p.D426H | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV63787995, COSV63792007; called by muse, mutect2, varscan2
- DCAF13 | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 22/43 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as COSV52569362; called by muse, mutect2, varscan2
- DDIT3 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as COSV56258695; called by muse, mutect2, varscan2
- DGKH | c.830G>A p.W277* | Nonsense Mutation (SNP) | VAF 74/273 reads (27%) | catalogued as COSV99819616; called by muse, mutect2, varscan2
- DIAPH2 | c.1127A>T p.Q376L | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61292226; called by muse, mutect2, varscan2
- DMBT1 | c.189T>C p.G63= | Splice Region (SNP) | VAF 40/311 reads (13%) | catalogued as COSV57562383; called by muse, mutect2, varscan2
- DMXL2 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 23/121 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.35); catalogued as COSV51856312; called by muse, mutect2, varscan2
- DNAH11 | c.6422C>G p.S2141C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.105); catalogued as COSV60981614; called by muse, mutect2, varscan2
- DNAH3 | c.9324T>A p.D3108E | Missense Mutation (SNP) | VAF 26/196 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV54551957; called by muse, mutect2, varscan2
- DNAH5 | c.5869C>G p.P1957A | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54252350, COSV99449632; called by muse, mutect2, varscan2
- DNMT3B | c.1243C>A p.Q415K | Missense Mutation (SNP) | VAF 28/298 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52415833; called by muse, mutect2
- DOCK1 | c.613C>G p.Q205E | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.85); PolyPhen benign (0.041); catalogued as COSV54760269; called by muse, mutect2, varscan2
- DOP1A | c.5083C>T p.Q1695* | Nonsense Mutation (SNP) | VAF 15/72 reads (21%) | catalogued as COSV99382193; called by muse, mutect2, varscan2
- DUSP11 | c.1024T>C p.S342P | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.715); catalogued as COSV55596297; called by muse, mutect2, varscan2
- EDA | c.242C>T p.S81L | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs780456712, COSV58879051; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EEF1A1 | c.458A>G p.N153S | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.488); catalogued as COSV100303454; called by muse, mutect2, varscan2
- EHD3 | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 32/64 reads (50%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.886); catalogued as rs201814896, COSV100434781, COSV59029271; called by muse, mutect2, varscan2
- ELOVL2 | c.163T>C p.Y55H | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs773854155, COSV61157122; called by muse, mutect2, varscan2
- EP300 | c.4856T>C p.I1619T | Missense Mutation (SNP) | VAF 38/162 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.121); catalogued as COSV54345704; called by muse, mutect2, varscan2
- EPS8 | c.362C>G p.S121* | Nonsense Mutation (SNP) | VAF 40/99 reads (40%) | catalogued as COSV99843722; called by muse, mutect2, varscan2
- ERH | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.034); catalogued as COSV53681132; called by muse, mutect2, varscan2
- ETV4 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.043); catalogued as rs776306922, COSV100081499, COSV60043769; called by muse, varscan2
- EVPL | c.5200G>T p.E1734* | Nonsense Mutation (SNP) | VAF 15/78 reads (19%) | catalogued as COSV101440980, COSV101440985; called by muse, mutect2, varscan2
- EVPL | c.4746G>C p.Q1582H | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.747); catalogued as COSV101440981; called by muse, mutect2
- FAM13B | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV50374346; called by muse, mutect2, varscan2
- FAM166A | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 35/75 reads (47%) | catalogued as COSV100458237; called by muse, mutect2, varscan2
- FAM166A | c.458C>G p.P153R | Missense Mutation (SNP) | VAF 31/72 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV61119045; called by muse, mutect2, varscan2
- FAM189B | c.995C>A p.S332* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as COSV100617566; called by muse, mutect2, varscan2
- FAM204A | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.676); catalogued as COSV64988045; called by muse, mutect2, varscan2
- FAM83E | c.1318C>T p.R440C | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs781707903, COSV52378837; called by muse, mutect2, varscan2
- FBXL5 | c.1946C>T p.S649L | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.255); catalogued as COSV58010848, COSV58013862; called by muse, mutect2, varscan2
- FDCSP | c.64C>T p.Q22* | Nonsense Mutation (SNP) | VAF 26/181 reads (14%) | catalogued as COSV100525862, COSV58764649; called by muse, mutect2, varscan2
- FER | c.1097C>T p.S366L | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.024); catalogued as COSV55305904; called by muse, mutect2, varscan2
- FGF23 | c.199C>G p.Q67E | Missense Mutation (SNP) | VAF 47/130 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as CM1412489, COSV52978050, COSV99426424; called by muse, mutect2, varscan2
- FGFR2 | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 23/194 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as rs374993905; ClinVar: not provided; called by muse, mutect2, varscan2
- FHOD1 | c.3445G>A p.D1149N | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV50769937; called by muse, mutect2, varscan2
- FRS2 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 48/122 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV54729858; called by muse, mutect2, varscan2
- FYB2 | c.1335G>C p.Q445H | Missense Mutation (SNP) | VAF 14/92 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV58589352; called by muse, mutect2, varscan2
- FZD10 | c.813C>A p.C271* | Nonsense Mutation (SNP) | VAF 24/162 reads (15%) | catalogued as COSV57475876, COSV99969623; called by muse, mutect2, varscan2
- FZD10 | c.1333G>T p.G445W | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57474313, COSV57475915; called by muse, mutect2, varscan2
- GABRR1 | c.1001C>G p.S334C | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65620710; called by muse, mutect2, varscan2
- GBF1 | c.3283C>T p.R1095W (on ENST00000369983 / NM_001377137.1; = p.R1094W on NM_004193.3) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374309391; called by muse, mutect2, varscan2
- GCOM1 | c.312C>G p.I104M | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51092529; called by muse, mutect2, varscan2
- GH2 | c.616G>A p.V206M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs751837455, COSV60427888; called by muse, mutect2, varscan2
- GIMAP4 | c.747G>C p.E249D | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.734); catalogued as rs770039406, COSV55433529, COSV55434673, COSV99750290; called by muse, mutect2, varscan2
- GJD3 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61606053; called by muse, mutect2, varscan2
- GLTP | c.135C>G p.I45M | Missense Mutation (SNP) | VAF 33/179 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.384); catalogued as COSV59173774; called by muse, mutect2, varscan2
- GP2 | c.67C>A p.L23M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.876); catalogued as COSV56896667; called by muse, varscan2
- GRM4 | c.1870G>A p.E624K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65219759; called by muse, mutect2, varscan2
- GRM6 | c.2539C>T p.P847S | Missense Mutation (SNP) | VAF 37/173 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51449553, COSV99179559; called by muse, mutect2, varscan2
- H2AC14 | c.89G>A p.R30Q | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100297656, COSV60798844; called by muse, mutect2, varscan2
- HEPACAM2 | c.1207G>C p.E403Q (on ENST00000394468 / NM_001039372.4; = p.E391Q on NM_198151.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59063423; called by muse, mutect2, varscan2
- HIF3A | c.1133G>C p.G378A (on ENST00000377670 / NM_152795.4; = p.G309A on NM_022462.4) | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.48); catalogued as rs755580944, COSV52204522; called by muse, mutect2, varscan2
- HIP1 | c.2452G>C p.E818Q | Missense Mutation (SNP) | VAF 54/295 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.131); catalogued as COSV61191538; called by muse, mutect2, varscan2
- HK3 | c.454G>C p.D152H | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV52844608; called by muse, mutect2, varscan2
- HLA-DQA1 | c.157G>C p.D53H | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58238109; called by muse, mutect2
- HMCN1 | c.15210G>C p.Q5070H | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as COSV54941922; called by muse, mutect2
- HNRNPCL1 | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 32/103 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.317); catalogued as rs745577551, COSV58615170; called by muse, mutect2, varscan2
- HNRNPU | c.1795G>C p.E599Q (on ENST00000283179; = p.E661Q on NM_004501.3) | Missense Mutation (SNP) | VAF 35/232 reads (15%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.991); catalogued as COSV51694343; called by muse, mutect2, varscan2
- HOXD9 | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.253); catalogued as COSV50895641; called by muse, mutect2, varscan2
- HSPA8 | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 57/102 reads (56%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.066); catalogued as COSV57086384, COSV99914288; called by muse, mutect2, varscan2
- HSPA8 | c.574G>C p.E192Q | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV57082500, COSV57082908; called by muse, mutect2, varscan2
- HTR1D | c.1007C>T p.A336V | Missense Mutation (SNP) | VAF 26/111 reads (23%) | SIFT tolerated (0.37); PolyPhen benign (0.023); catalogued as rs758749231, COSV58449446; called by muse, mutect2, varscan2
- HUS1B | c.416G>A p.R139K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.152); catalogued as COSV57871930; called by muse, mutect2, varscan2
- IKZF5 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 12/115 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1290369110, COSV100924768; called by muse, mutect2
- IL10RB | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); catalogued as COSV51618115; called by muse, mutect2, varscan2
- IL6R | c.151G>C p.E51Q | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.155); catalogued as COSV59819516; called by muse, mutect2, varscan2
- ILK | c.1197G>C p.E399D | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV54992595; called by muse, mutect2, varscan2
- INCENP | c.1780G>A p.E594K (on ENST00000394818 / NM_001040694.2; = p.E590K on NM_020238.3) | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1363372627, COSV53914060; called by muse, mutect2, varscan2
- IRAK2 | c.1210-1G>T p.X404_splice | Splice Site (SNP) | VAF 33/62 reads (53%) | catalogued as rs1415869805, COSV56535837; called by muse, mutect2, varscan2
- ITGB4 | c.2252G>A p.R751Q | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs774290507, COSV52332805; called by muse, mutect2, varscan2
- JUP | c.1182G>C p.K394N | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.082); catalogued as COSV60279471; called by muse, mutect2, varscan2
- KCNA1 | c.92A>G p.D31G | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV101230282, COSV66838705; called by muse, mutect2, varscan2
- KCNA1 | c.594C>A p.F198L | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66838710; called by muse, mutect2, varscan2
- KCNIP4 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV66270317; called by muse, mutect2, varscan2
- KCNJ8 | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 54/131 reads (41%) | SIFT tolerated (0.64); PolyPhen benign (0.03); catalogued as COSV53718392; called by muse, mutect2, varscan2
- KIF1B | c.3054A>T p.E1018D (on ENST00000377086 / NM_001365952.1; = p.E972D on NM_015074.3) | Missense Mutation (SNP) | VAF 112/465 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as COSV55816159; called by muse, mutect2, varscan2
- KLHL21 | c.1494G>A p.M498I | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV66553078; called by muse, mutect2, varscan2
- KMT2E | c.5440C>T p.H1814Y | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs1187515525, COSV57579801; called by muse, mutect2, varscan2
- KRT25 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV56444472, COSV56446589; called by muse, mutect2, varscan2
- L1CAM | c.950C>A p.S317* | Nonsense Mutation (SNP) | VAF 84/152 reads (55%) | catalogued as COSV100649484; called by muse, mutect2, varscan2
- LAMA3 | c.2893G>A p.E965K | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV58080392; called by muse, mutect2, varscan2
- LCN2 | c.101G>A p.S34N | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0.011); catalogued as rs746216339, COSV52981967; called by muse, mutect2, varscan2
- LCOR | c.3932G>C p.R1311T | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV53718480; called by muse, mutect2, varscan2
- LGI1 | c.349C>G p.L117V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65059388; called by muse, mutect2, varscan2
- LONP1 | c.1845G>C p.Q615H | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV61502096; called by muse, mutect2, varscan2
- LOXL2 | c.437C>T p.T146I | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs1204437560, COSV66693567; called by muse, mutect2, varscan2
- LRBA | c.5157C>G p.F1719L | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.97); catalogued as COSV63964963; called by muse, mutect2, varscan2
- LRG1 | c.827C>G p.P276R | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100015194, COSV56706070; called by muse, mutect2, varscan2
- LRIG2 | c.572C>G p.S191* | Nonsense Mutation (SNP) | VAF 36/110 reads (33%) | catalogued as rs759934553, COSV100743010; called by muse, mutect2, varscan2
- LRP2 | c.10070C>T p.S3357F | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV55574533; called by muse, mutect2, varscan2
- LRP5 | c.3304G>A p.E1102K | Missense Mutation (SNP) | VAF 49/101 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); catalogued as rs970458513, CM153251, COSV53723710; called by muse, mutect2, varscan2
- LRRK2 | c.3482G>C p.R1161T | Missense Mutation (SNP) | VAF 39/191 reads (20%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100111406, COSV54170745; called by muse, mutect2, varscan2
- LYPLAL1 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as COSV65107166; called by muse, mutect2, varscan2
- MACF1 | c.8212G>A p.D2738N | Missense Mutation (SNP) | VAF 11/91 reads (12%) | catalogued as COSV57144354; called by muse, mutect2, varscan2
- MAGEB6 | c.1187T>A p.I396K | Missense Mutation (SNP) | VAF 69/103 reads (67%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV66873103; called by muse, mutect2, varscan2
- MAP3K12 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV57236120; called by muse, mutect2, varscan2
- MAP3K13 | c.2549C>G p.S850C | Missense Mutation (SNP) | VAF 44/155 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV53997544; called by muse, mutect2, varscan2
- MAP3K2 | c.1141G>C p.E381Q | Missense Mutation (SNP) | VAF 22/134 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); catalogued as COSV61294028, COSV61296379; called by muse, mutect2, varscan2
- MAP3K21 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1157699639, COSV100786320; called by muse, mutect2, varscan2
- MAP4K5 | c.1412G>A p.R471Q | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT tolerated (0.59); PolyPhen benign (0.044); catalogued as rs1289006325, COSV99184870; called by muse, mutect2, varscan2
- MBD4 | c.453C>G p.I151M | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.459); catalogued as COSV51445884; called by muse, mutect2, varscan2
- MED13 | c.5263G>C p.E1755Q | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.723); catalogued as COSV67263133, COSV67267094; called by muse, mutect2, varscan2
- MKI67 | c.3169G>A p.E1057K | Missense Mutation (SNP) | VAF 69/493 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.828); catalogued as rs200086427, COSV64076987; called by muse, mutect2, varscan2
- MLH3 | c.2147C>G p.S716C | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.818); catalogued as COSV53159092; called by muse, mutect2, varscan2
- MMADHC | c.558G>T p.M186I | Missense Mutation (SNP) | VAF 51/183 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV57574744; called by muse, mutect2, varscan2
- MMS19 | c.1033C>G p.L345V | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59137436; called by muse, mutect2, varscan2
- MNDA | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 19/116 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.045); catalogued as rs1486215394, COSV63742134; called by muse, mutect2, varscan2
- MORF4L1 | c.346C>T p.Q116* (on ENST00000331268 / NM_206839.2; = p.Q77* on NM_006791.4) | Nonsense Mutation (SNP) | VAF 18/88 reads (20%) | catalogued as COSV100489225; called by muse, mutect2, varscan2
- MROH5 | c.3463A>T p.R1155W | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100267464; called by muse, mutect2, varscan2
- MROH7 | c.1400A>T p.Q467L | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV59877921; called by muse, mutect2, varscan2
- MTCL1 | c.2347G>C p.E783Q (on ENST00000306329 / NM_001378206.1; = p.E423Q on NM_015210.4) | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV60411818; called by muse, mutect2, varscan2
- MUC16 | c.32809C>G p.L10937V | Missense Mutation (SNP) | VAF 48/163 reads (29%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.11); catalogued as rs746420551, COSV67461182, COSV67484595; called by muse, mutect2, varscan2
- MUC5B | c.15176C>T p.S5059L | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs199819779, COSV71595598; called by muse, mutect2, varscan2
- MYBPC1 | c.1414C>T p.Q472* (on ENST00000550270 / NM_206820.2; = p.Q497* on NM_002465.4) | Nonsense Mutation (SNP) | VAF 74/189 reads (39%) | catalogued as COSV100638295, COSV62254636; called by muse, mutect2, varscan2
- MYH10 | c.2167G>T p.E723* | Nonsense Mutation (SNP) | VAF 9/53 reads (17%) | catalogued as COSV99346422; called by muse, mutect2, varscan2
- MYH13 | c.1186G>A p.E396K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as COSV52842815; called by muse, mutect2, varscan2
- MYO16 | c.4970C>G p.P1657R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.708); catalogued as COSV62761883; called by muse, mutect2, varscan2
- MYO1F | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 33/189 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.777); catalogued as COSV100596593, COSV57792110; called by muse, mutect2, varscan2
- MYO9B | c.6473G>T p.*2158Lext*95 | Nonstop Mutation (SNP) | VAF 5/15 reads (33%) | catalogued as COSV55728728, COSV99812636; called by muse, mutect2
- MYPN | c.3647G>C p.R1216T | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.886); catalogued as COSV62739488; called by muse, mutect2, varscan2
- N4BP2 | c.2633C>A p.S878* | Nonsense Mutation (SNP) | VAF 11/52 reads (21%) | catalogued as COSV99789316; called by muse, mutect2, varscan2
- NACC1 | c.1199G>A p.R400Q | Missense Mutation (SNP) | VAF 12/108 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52836029; called by muse, mutect2, varscan2
- NAPRT | c.1094G>C p.R365P | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs761418207, COSV52788879; called by muse, mutect2, varscan2
- NAV1 | c.2390C>T p.S797L | Missense Mutation (SNP) | VAF 148/418 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs767782492, COSV55226497; called by muse, varscan2
- NAV1 | c.2438C>T p.S813L | Missense Mutation (SNP) | VAF 142/352 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as COSV55226509; called by muse, varscan2
- NCOR1 | c.3928G>C p.D1310H | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.557); catalogued as COSV51971464, COSV51996166; called by muse, mutect2, varscan2
- NDUFS8 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.026); catalogued as COSV50291435; called by muse, mutect2, varscan2
- NEB | c.3141C>G p.I1047M | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.805); catalogued as COSV51447807; called by muse, mutect2, varscan2
- NEFH | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.327); catalogued as COSV60220695; called by muse, mutect2, varscan2
- NEK11 | c.1120C>T p.R374* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | catalogued as rs761832854, COSV100797921; called by muse, mutect2, varscan2
- NES | c.3706C>T p.Q1236* | Nonsense Mutation (SNP) | VAF 52/130 reads (40%) | catalogued as COSV100957767; called by muse, mutect2, varscan2
- NIPAL4 | c.238C>G p.L80V | Missense Mutation (SNP) | VAF 38/99 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV61731130; called by muse, mutect2, varscan2
- NUAK1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.097); catalogued as COSV54608316; called by muse, mutect2, varscan2
- NUDT22 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV54175852; called by muse, mutect2, varscan2
- NUP188 | c.883C>T p.Q295* | Nonsense Mutation (SNP) | VAF 12/54 reads (22%) | catalogued as COSV101001502; called by muse, mutect2, varscan2
- NUP188 | c.3892G>C p.E1298Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as COSV65364929; called by muse, varscan2
- NUP188 | c.4046G>T p.G1349V | Missense Mutation (SNP) | VAF 20/47 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV65362658, COSV65364934; called by muse, mutect2, varscan2
- OBSCN | c.19804G>A p.D6602N | Missense Mutation (SNP) | VAF 90/271 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV63479912; called by muse, mutect2, varscan2
- OGA | c.2452G>A p.E818K | Missense Mutation (SNP) | VAF 43/179 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.177); catalogued as COSV63383360; called by muse, mutect2, varscan2
- OR2M3 | c.215T>A p.M72K | Missense Mutation (SNP) | VAF 85/454 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as COSV71759283; called by muse, mutect2, varscan2
- OR8A1 | c.691G>C p.E231Q | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.363); catalogued as COSV52510217, COSV52510454; called by muse, mutect2, varscan2
- OR8B2 | c.453G>A p.M151I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV100899506; called by muse, mutect2, varscan2
- PAX1 | c.1154G>T p.G385V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV68273417; called by muse, mutect2, varscan2
- PBRM1 | c.4119G>C p.K1373N (on ENST00000296302 / NM_001366071.2; = p.K1321N on NM_018313.5) | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56304285; called by muse, mutect2, varscan2
- PCDHA4 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.902); catalogued as COSV63546128; called by muse, mutect2, varscan2
- PCDHB8 | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 17/169 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV99177447; called by muse, mutect2, varscan2
- PDCD10 | c.244C>G p.R82G | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV67102093, COSV67103181; called by muse, mutect2, varscan2
- PDE8A | c.229C>G p.Q77E | Missense Mutation (SNP) | VAF 25/101 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59640575; called by muse, mutect2, varscan2
- PDHX | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.951); catalogued as COSV57169092; called by muse, mutect2, varscan2
- PDZD2 | c.5218G>A p.D1740N | Missense Mutation (SNP) | VAF 50/163 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs779003315, COSV56861524, COSV56864745; called by muse, mutect2, varscan2
- PFKM | c.1936G>C p.E646Q | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV56660407; called by muse, mutect2, varscan2
- PGBD1 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 35/115 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.895); catalogued as COSV52556137; called by muse, mutect2, varscan2
- PGR | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.187); catalogued as COSV54810835; called by muse, mutect2, varscan2
- POLRMT | c.1458C>G p.V486= | Splice Region (SNP) | VAF 4/13 reads (31%) | catalogued as rs985953570, COSV101646104; called by muse, mutect2
- POU4F2 | c.1117G>A p.E373K | Missense Mutation (SNP) | VAF 20/134 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55586765; called by muse, mutect2, varscan2
- PPP2R3A | c.127G>A p.D43N | Missense Mutation (SNP) | VAF 35/118 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.028); catalogued as COSV53870841; called by muse, mutect2, varscan2
- PPP6R3 | c.1678G>A p.D560N (on ENST00000393800 / NM_001352375.2; = p.D480N on NM_018312.5) | Missense Mutation (SNP) | VAF 60/309 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV55736014; called by muse, mutect2, varscan2
- PRKAR2B | c.1027C>G p.R343G | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.633); catalogued as rs1489977996, COSV55923139, COSV55927941; called by muse, mutect2, varscan2
- PRPF4B | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV61785870; called by muse, mutect2, varscan2
- PSG11 | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 120/461 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100106269, COSV60457883; called by muse, mutect2, varscan2
- PSMB8 | c.655C>G p.L219V (on ENST00000374882 / NM_148919.4; = p.L215V on NM_004159.5) | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV62755776; called by muse, mutect2, varscan2
- PTPDC1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as rs755043926, COSV100944309, COSV64718450; called by muse, mutect2, varscan2
- PTPRH | c.812C>T p.S271L | Missense Mutation (SNP) | VAF 84/264 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.905); catalogued as COSV54750224; called by muse, mutect2, varscan2
- PTPRZ1 | c.5425G>A p.E1809K | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV66445622; called by muse, mutect2, varscan2
- PUM2 | c.421G>T p.D141Y | Missense Mutation (SNP) | VAF 20/111 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.753); catalogued as COSV57585417; called by muse, mutect2, varscan2
- PWP1 | c.1307C>T p.S436F | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.222); catalogued as COSV69833464; called by muse, mutect2, varscan2
- PWWP3A | c.707C>T p.S236L (on ENST00000627377; = p.S235L on NM_032853.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.073); catalogued as rs1391393945, COSV60900773; called by muse, mutect2, varscan2
- RAI14 | c.1000G>A p.D334N | Missense Mutation (SNP) | VAF 30/146 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs1458490330, COSV54303590; called by muse, mutect2, varscan2
- RARG | c.941T>C p.F314S | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58434782; called by muse, varscan2
- RBM14 | c.1933T>C p.Y645H | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV59560750; called by muse, mutect2, varscan2
- RBM42 | c.524C>G p.S175C | Missense Mutation (SNP) | VAF 88/276 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV52899159; called by muse, mutect2, varscan2
- RBPJ | c.832G>A p.D278N | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV60757098; called by muse, mutect2, varscan2
- RBSN | c.1311G>C p.L437F | Missense Mutation (SNP) | VAF 24/122 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.092); catalogued as COSV53795612; called by muse, mutect2, varscan2
- REEP3 | c.319A>G p.I107V | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV53427371; called by muse, mutect2, varscan2
- RELN | c.9154G>A p.E3052K | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.684); catalogued as COSV59014672; called by muse, mutect2, varscan2
- RETREG1 | c.743C>G p.S248* (on ENST00000306320 / NM_001034850.2; = p.S107* on NM_019000.4) | Nonsense Mutation (SNP) | VAF 70/258 reads (27%) | catalogued as COSV60446228; called by muse, mutect2, varscan2
- REXO5 | c.2148G>C p.K716N | Missense Mutation (SNP) | VAF 52/256 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as COSV54474800; called by muse, mutect2, varscan2
- RGL4 | c.1210G>C p.D404H | Missense Mutation (SNP) | VAF 16/94 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as COSV51945414; called by muse, mutect2, varscan2
- RGS6 | c.1167A>T p.Q389H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as COSV59599350; called by muse, mutect2, varscan2
- RHD | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 33/175 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59647283; called by muse, mutect2, varscan2
- RHO | c.819C>A p.F273L | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV56214643; called by muse, mutect2, varscan2
- RIOK2 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as COSV51615141; called by muse, mutect2, varscan2
- RIPK1 | c.929A>C p.N310T | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV52531807; called by muse, varscan2
- RMI1 | c.773C>T p.T258I | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57937970; called by muse, mutect2, varscan2
- RND1 | c.503C>G p.S168* | Nonsense Mutation (SNP) | VAF 11/66 reads (17%) | catalogued as COSV100552239; called by muse, mutect2, varscan2
- RWDD4 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 16/123 reads (13%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV58394659; called by muse, mutect2, varscan2
- RYR2 | c.4147C>T p.R1383C | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as COSV63675806; called by muse, mutect2
- RYR3 | c.7138C>G p.L2380V (on ENST00000389232; = p.L2381V on NM_001036.6) | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV66808630, COSV66810839; called by muse, mutect2, varscan2
- RYR3 | c.8068G>C p.E2690Q (on ENST00000389232; = p.E2691Q on NM_001036.6) | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.95); catalogued as COSV66808634; called by muse, mutect2, varscan2
- SALL1 | c.1159G>C p.A387P | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.543); catalogued as COSV51764696; called by muse, mutect2, varscan2
- SCAND1 | c.484G>T p.E162* | Nonsense Mutation (SNP) | VAF 40/48 reads (83%) | catalogued as COSV100019007; called by muse, mutect2, varscan2
- SCN4A | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101438674; called by muse, mutect2
- SCN5A | c.964G>C p.D322H | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.526); catalogued as COSV61124121, COSV61140978; called by muse, mutect2, varscan2
- SENP3 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 12/19 reads (63%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.028); catalogued as COSV53437927; called by muse, mutect2, varscan2
- SERHL2 | c.636G>C p.Q212H | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.571); catalogued as rs779038651, COSV59670180; called by muse, mutect2, varscan2
- SETD6 | c.631G>C p.E211Q (on ENST00000219315 / NM_001160305.4; = p.E187Q on NM_024860.3) | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV50751829; called by muse, mutect2, varscan2
- SETD6 | c.703G>A p.E235K (on ENST00000219315 / NM_001160305.4; = p.E211K on NM_024860.3) | Missense Mutation (SNP) | VAF 40/220 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs753959451, COSV50751833; called by muse, mutect2, varscan2
- SF3A1 | c.844G>A p.V282M | Missense Mutation (SNP) | VAF 26/99 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53171342; called by muse, mutect2, varscan2
- SGCZ | c.529G>A p.E177K | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV66044209; called by muse, mutect2, varscan2
- SHISA2 | c.346G>A p.V116M | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs113091428; called by muse, mutect2, varscan2
- SHISA5 | c.620C>A p.P207Q | Missense Mutation (SNP) | VAF 40/116 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56498053; called by muse, mutect2, varscan2
- SIPA1L3 | c.154G>A p.E52K | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.43); PolyPhen benign (0.083); catalogued as rs753429177, COSV55917980; called by muse, mutect2, varscan2
- SLC1A1 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 67/142 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52058057; called by muse, mutect2, varscan2
- SLC25A41 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58599578; called by muse, mutect2, varscan2
- SLC36A3 | c.1004C>G p.S335C | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV58857253, COSV58858386; called by muse, mutect2, varscan2
- SMARCA2 | c.2095C>G p.Q699E | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as COSV61812733; called by muse, mutect2, varscan2
- SMCO1 | c.219G>T p.L73F | Missense Mutation (SNP) | VAF 25/75 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.069); catalogued as COSV58837061; called by muse, mutect2, varscan2
- SNX10 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 28/197 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.026); catalogued as COSV58402517; called by muse, mutect2, varscan2
- SNX33 | c.1635G>T p.M545I | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.53); PolyPhen benign (0.233); catalogued as COSV57914598; called by muse, mutect2, varscan2
- SPAG6 | c.576T>A p.S192R | Missense Mutation (SNP) | VAF 35/113 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.797); catalogued as COSV57623997; called by muse, mutect2, varscan2
- SPANXD | c.143C>T p.S48L | Missense Mutation (SNP) | VAF 83/244 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.992); catalogued as rs199908821, COSV65152611; called by muse, mutect2, varscan2
- SPEG | c.2986G>A p.D996N | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56679755; called by muse, mutect2, varscan2
- SPTB | c.4783G>A p.E1595K | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs756327499, COSV67631249; called by muse, mutect2, varscan2
- SPTBN2 | c.4170G>C p.Q1390H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59461365; called by muse, mutect2, varscan2
- SPTBN4 | c.1188C>G p.I396M | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV58958903; called by muse, mutect2, varscan2
- SRRM2 | c.1607C>T p.S536F | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV57072744; called by muse, mutect2, varscan2
- STAG2 | c.2539C>T p.Q847* | Nonsense Mutation (SNP) | VAF 39/64 reads (61%) | catalogued as COSV54372457; called by muse, mutect2, varscan2
- SURF6 | c.913C>T p.R305C | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs200738573, COSV64395379; called by muse, mutect2, varscan2
- SYDE2 | c.2455C>G p.Q819E | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV52315410, COSV52318123; called by muse, mutect2, varscan2
- SYMPK | c.2431G>A p.V811M | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.672); catalogued as COSV55615884; called by muse, mutect2, varscan2
- SYNE1 | c.5860C>T p.Q1954* (on ENST00000367255 / NM_182961.4; = p.Q1961* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 25/143 reads (17%) | catalogued as COSV99580062; called by muse, mutect2, varscan2
- SYNE1 | c.1435C>G p.P479A (on ENST00000367255 / NM_182961.4; = p.P486A on NM_033071.3) | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT tolerated (0.17); PolyPhen benign (0.101); catalogued as COSV55103665; called by muse, mutect2, varscan2
- SYT14 | c.1467T>A p.F489L | Missense Mutation (SNP) | VAF 31/146 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55063837; called by muse, mutect2, varscan2
- TACC2 | c.7437G>C p.Q2479H (on ENST00000334433; = p.Q557H on NM_006997.4) | Missense Mutation (SNP) | VAF 35/187 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.727); catalogued as COSV53289847; called by muse, mutect2, varscan2
- TARS3 | c.1806G>C p.L602F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV60109590; called by muse, mutect2, varscan2
- TBR1 | c.838A>C p.N280H | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV67419198; called by muse, mutect2, varscan2
- TBX20 | c.481C>G p.R161G | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68783843, COSV68785950; called by muse, mutect2, varscan2
- TCEANC | c.807G>C p.L269F (on ENST00000380600 / NM_001297563.2; = p.L299F on NM_152634.4) | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59041134; called by muse, mutect2, varscan2
- TET1 | c.1849C>T p.Q617* | Nonsense Mutation (SNP) | VAF 26/115 reads (23%) | catalogued as COSV65381667; called by muse, mutect2, varscan2
- TF | c.1854G>C p.K618N | Missense Mutation (SNP) | VAF 66/168 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV53924247; called by muse, mutect2, varscan2
- TFIP11 | c.1059C>A p.F353L | Missense Mutation (SNP) | VAF 23/142 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV53227830; called by muse, mutect2, varscan2
- THAP9 | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.055); catalogued as COSV56357916; called by muse, varscan2
- TIMD4 | c.236G>T p.R79I | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.723); catalogued as COSV50860361; called by muse, mutect2, varscan2
- TMCO4 | c.1496C>G p.S499C | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as rs752530872, COSV53877391; called by muse, mutect2, varscan2
- TMEM132D | c.854G>A p.R285H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.027); catalogued as rs751041490, COSV70594645; called by muse, mutect2, varscan2
- TMPO | c.1345G>C p.D449H | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); catalogued as COSV58463745; called by muse, mutect2, varscan2
- TPR | c.988G>C p.E330Q | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as COSV66602945, COSV66605232; called by muse, mutect2, varscan2
- TRAF2 | c.973G>C p.E325Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as COSV56041496; called by muse, mutect2, varscan2
- TRAPPC9 | c.1880T>G p.F627C | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66909736; called by muse, mutect2, varscan2
- TREX1 | c.202T>G p.S68A (on ENST00000625293 / NM_033629.6; = p.S58A on NM_007248.5) | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.485); catalogued as COSV56498048; called by muse, mutect2, varscan2
- TRIOBP | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 26/142 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs758476559, COSV60373429; called by muse, mutect2, varscan2
- TRPS1 | c.2784G>A p.S928= (on ENST00000220888 / NM_001330599.2; = p.S941= on NM_014112.5 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 32/216 reads (15%) | catalogued as rs774932870, COSV55262248; called by muse, mutect2, varscan2
- TRRAP | c.4657C>G p.P1553A (on ENST00000359863 / NM_001244580.1; = p.P1535A on NM_003496.3) | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as COSV62842302, COSV62854498; called by muse, varscan2
- TTC16 | c.627C>G p.F209L | Missense Mutation (SNP) | VAF 15/106 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58854396; called by muse, mutect2, varscan2
- TTN | c.49496G>A p.R16499Q (on ENST00000591111; = p.R9075Q on NM_003319.4) | Missense Mutation (SNP) | VAF 10/43 reads (23%) | PolyPhen benign (0.314); catalogued as rs547224785, COSV60050043; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- U2SURP | c.451G>C p.D151H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as COSV67533261; called by muse, mutect2, varscan2
- UBR1 | c.5048G>C p.R1683T | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV51936489; called by muse, mutect2, varscan2
- USP4 | c.2024C>G p.S675* | Nonsense Mutation (SNP) | VAF 22/105 reads (21%) | catalogued as COSV99649801; called by muse, mutect2, varscan2
- VAT1 | c.25G>C p.E9Q | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV63040528; called by muse, mutect2, varscan2
- VPS37C | c.67G>C p.D23H | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.483); catalogued as COSV57110092; called by muse, mutect2, varscan2
- VSTM1 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.284); catalogued as rs765151792, COSV58076897; called by muse, mutect2
- WDR36 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); catalogued as COSV72411493; called by muse, mutect2, varscan2
- WDR43 | c.1492C>T p.P498S | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV68019645; called by muse, mutect2, varscan2
- XRCC1 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1041258260, COSV53453213; called by muse, mutect2, varscan2
- YTHDC2 | c.2256C>A p.F752L | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.223); catalogued as COSV50753882; called by muse, mutect2, varscan2
- ZBTB7C | c.1090C>T p.Q364* | Nonsense Mutation (SNP) | VAF 17/86 reads (20%) | catalogued as COSV100134620, COSV59689284; called by muse, mutect2, varscan2
- ZDHHC14 | c.631T>A p.Y211N | Missense Mutation (SNP) | VAF 43/216 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58193126, COSV58196782; called by muse, mutect2, varscan2
- ZEB2 | c.3280G>C p.E1094Q | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); catalogued as COSV57953550, COSV57956836; called by muse, mutect2, varscan2
- ZFAND1 | c.223G>A p.V75M | Missense Mutation (SNP) | VAF 48/125 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV55108638; called by muse, mutect2, varscan2
- ZFHX3 | c.7769C>T p.S2590F | Missense Mutation (SNP) | VAF 67/196 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV51711550, COSV51735869; called by muse, mutect2, varscan2
- ZFHX3 | c.3463G>A p.D1155N | Missense Mutation (SNP) | VAF 14/141 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); catalogued as COSV51735883; called by muse, mutect2, varscan2
- ZFP36L1 | c.743dup p.N248Kfs*2 | Frame Shift Ins (INS) | VAF 25/172 reads (15%) | catalogued as rs775692081; called by mutect2, pindel, varscan2
- ZGRF1 | c.3986C>T p.S1329L | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV58411360; called by muse, mutect2, varscan2
- ZNF107 | c.704A>T p.K235M | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV61332069; called by muse, mutect2, varscan2
- ZNF175 | c.710C>G p.S237C | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV51798483; called by muse, mutect2
- ZNF181 | c.1494C>A p.F498L | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67627278; called by muse, mutect2, varscan2
- ZNF213 | c.789G>C p.Q263H | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.28); catalogued as COSV67728305; called by muse, mutect2, varscan2
- ZNF35 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1559485442, COSV56077480; called by muse, mutect2, varscan2
- ZNF442 | c.50C>G p.S17C | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.7); catalogued as COSV54423315; called by muse, mutect2, varscan2
- ZNF473 | c.684G>C p.W228C | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV54525176; called by muse, mutect2, varscan2
- ZNF548 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 35/128 reads (27%) | catalogued as COSV100278308; called by muse, mutect2, varscan2
- ZNF556 | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 29/86 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs367809549; called by muse, mutect2, varscan2
- ZNF577 | c.182C>G p.S61* | Nonsense Mutation (SNP) | VAF 28/96 reads (29%) | catalogued as COSV100031318; called by muse, mutect2, varscan2
- ZNF638 | c.325C>T p.H109Y | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT tolerated (1); PolyPhen possibly damaging (0.651); catalogued as rs765518639, COSV52496968; called by muse, mutect2, varscan2
- ZNF683 | c.1252C>T p.R418C (on ENST00000403843; = p.R398C on NM_173574.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.312); catalogued as rs750051965, COSV62873582, COSV62874562; called by muse, mutect2, varscan2
- ZNF761 | c.187C>G p.Q63E | Missense Mutation (SNP) | VAF 18/159 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.209); catalogued as COSV61889493; called by muse, mutect2, varscan2
- ZNF804A | c.3529C>G p.L1177V | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.795); catalogued as COSV56471617; called by muse, mutect2, varscan2
- ZNF804B | c.3578C>T p.S1193L | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV60843294; called by muse, mutect2, varscan2
- ZSWIM8 | c.4829G>A p.G1610E (on ENST00000605216 / NM_001242487.2; = p.G1615E on NM_015037.3) | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.453); catalogued as COSV55217936; called by muse, mutect2, varscan2
- ANOS1 | c.478del p.V160* | Frame Shift Del (DEL) | VAF 31/71 reads (44%) | called by mutect2, pindel, varscan2
- IKBKB | c.716_743del p.S239Tfs*2 | Frame Shift Del (DEL) | VAF 20/148 reads (14%) | called by mutect2, pindel
- LOXL3 | c.1827_1834del p.H609Qfs*9 | Frame Shift Del (DEL) | VAF 9/72 reads (13%) | called by mutect2, pindel, varscan2
- MAGEB6B | c.1057C>T p.P353S | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- NLRC5 | c.5026G>A p.D1676N | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.033); called by muse, mutect2
- POLR2A | c.2318G>A p.G773E | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRAMEF20 | c.1066T>G p.L356V | Missense Mutation (SNP) | VAF 157/1036 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PREX2 | c.3147-26_3153del p.X1049_splice | Splice Site (DEL) | VAF 6/48 reads (13%) | called by mutect2, pindel
- RARG | c.948_964del p.Q317Dfs*3 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | called by pindel, varscan2
- ABCA6 | c.897C>T p.V299= | Silent (SNP) | VAF 16/114 reads (14%) | catalogued as COSV52644921, COSV99446255; called by muse, mutect2, varscan2
- ACSF3 | c.72G>A p.A24= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as rs752720474, COSV58081814; called by muse, varscan2
- ACTR8 | c.849C>T p.D283= | Silent (SNP) | VAF 9/83 reads (11%) | catalogued as rs375835593; called by muse, mutect2, varscan2
- AMDHD2 | c.279C>G p.L93= | Silent (SNP) | VAF 20/113 reads (18%) | catalogued as rs150383216, COSV53551648; called by muse, mutect2, varscan2
- ANGPTL2 | c.423C>G p.L141= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV52232795, COSV99400987; called by muse, mutect2, varscan2
- ANO1 | c.885C>T p.F295= | Silent (SNP) | VAF 9/33 reads (27%) | catalogued as COSV60289256; called by muse, mutect2, varscan2
- ARG2 | c.477C>T p.L159= | Silent (SNP) | VAF 38/84 reads (45%) | catalogued as COSV55777172; called by muse, mutect2, varscan2
- ARHGAP11A | c.147A>G p.V49= | Silent (SNP) | VAF 65/265 reads (25%) | catalogued as COSV100853367; called by muse, mutect2, varscan2
- ARMC12 | c.582G>A p.L194= (on ENST00000373866 / NM_001286574.2; = p.L221= on NM_145028.5) | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV55361744; called by muse, varscan2
- ARMCX3 | c.81G>A p.L27= | Silent (SNP) | VAF 40/61 reads (66%) | catalogued as COSV57871678; called by muse, mutect2, varscan2
- ATP8A2 | c.2436G>A p.V812= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as rs1329587716, COSV54976932; called by muse, mutect2, varscan2
- BCL11A | c.1653C>T p.C551= (on ENST00000335712 / NM_001365609.1; = p.C585= on NM_018014.4) | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs1489297664, COSV100186404, COSV59633932; called by muse, mutect2, varscan2
- BMPER | c.1860T>A p.P620= | Silent (SNP) | VAF 18/83 reads (22%) | catalogued as COSV51831565; called by muse, varscan2
- C2CD2 | c.825C>T p.L275= | Silent (SNP) | VAF 10/40 reads (25%) | catalogued as COSV61600520; called by muse, mutect2, varscan2
- CACNG4 | c.78C>T p.I26= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV50926115; called by muse, mutect2, varscan2
- CALR3 | c.366G>A p.L122= | Silent (SNP) | VAF 37/111 reads (33%) | catalogued as COSV54171026; called by muse, varscan2
- CAMK2G | c.1413G>C p.G471= (on ENST00000423381 / NM_001367518.1; = p.G408= on NM_001222.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 61/267 reads (23%) | catalogued as COSV59485676; called by muse, mutect2, varscan2
- CAMK2G | c.1287G>A p.E429= (on ENST00000423381 / NM_001367518.1; = p.E366= on NM_001222.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 37/125 reads (30%) | catalogued as COSV59485695; called by muse, mutect2, varscan2
- CD40 | c.444C>G p.V148= | Silent (SNP) | VAF 85/173 reads (49%) | catalogued as COSV64847641, COSV64848276; called by muse, mutect2, varscan2
- CD46 | c.1176C>G p.L392= | Silent (SNP) | VAF 28/143 reads (20%) | catalogued as COSV59735561; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1506C>T p.L502= (on ENST00000357886 / NM_001365728.1; = p.L488= on NM_016082.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as COSV59428968; called by muse, mutect2, varscan2
- CEP170B | c.2517C>T p.V839= (on ENST00000453495; = p.V768= on NM_015005.3) | Silent (SNP) | VAF 27/48 reads (56%) | catalogued as rs775596743, COSV69026615; called by muse, mutect2, varscan2
- CILK1 | c.597C>G p.L199= | Silent (SNP) | VAF 51/191 reads (27%) | catalogued as COSV63153650, COSV63156000; called by muse, mutect2, varscan2
- CLK4 | c.747C>T p.F249= | Silent (SNP) | VAF 29/80 reads (36%) | catalogued as COSV60321114; called by muse, mutect2, varscan2
- CLPB | c.450C>T p.V150= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as COSV99578717; called by muse, mutect2, varscan2
- COLGALT1 | c.1629C>G p.L543= | Silent (SNP) | VAF 114/339 reads (34%) | catalogued as COSV53111570; called by muse, mutect2, varscan2
- CSF1 | c.1627C>T p.L543= | Silent (SNP) | VAF 18/117 reads (15%) | catalogued as rs764243383, COSV60035422; called by muse, mutect2, varscan2
- DAXX | c.264C>G p.L88= | Silent (SNP) | VAF 20/121 reads (17%) | catalogued as COSV56468007; called by muse, mutect2, varscan2
- DCTN5 | c.456C>G p.L152= | Silent (SNP) | VAF 34/88 reads (39%) | catalogued as COSV55616493; called by muse, mutect2, varscan2
- DHX37 | c.1902C>T p.Y634= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs570040386, COSV58135322; called by muse, mutect2, varscan2
- DISC1 | c.711C>T p.S237= | Silent (SNP) | VAF 29/55 reads (53%) | catalogued as COSV54418989; called by muse, varscan2
- DNAJC13 | c.5268G>A p.L1756= | Silent (SNP) | VAF 49/155 reads (32%) | catalogued as COSV53458233; called by muse, mutect2, varscan2
- EFTUD2 | c.1383C>T p.L461= | Silent (SNP) | VAF 44/96 reads (46%) | catalogued as rs1399830120, COSV68184524; called by muse, mutect2, varscan2
- EMC8 | c.12G>A p.V4= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV53666583; called by muse, mutect2, varscan2
- EXOC7 | c.2067G>A p.K689= (on ENST00000335146 / NM_001145297.4; = p.K607= on NM_015219.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV58037892; called by muse, mutect2, varscan2
- FAF1 | c.1398G>A p.V466= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV65644003; called by muse, mutect2, varscan2
- FAM83E | c.1317C>T p.L439= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as COSV52378842; called by muse, mutect2, varscan2
- FDCSP | c.249C>T p.S83= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as rs200937610, COSV58764470; called by muse, mutect2, varscan2
- FUBP3 | c.1269G>A p.E423= | Silent (SNP) | VAF 17/48 reads (35%) | catalogued as COSV60516769; called by muse, mutect2, varscan2
- GATA1 | c.1089C>G p.L363= | Silent (SNP) | VAF 9/17 reads (53%) | catalogued as COSV64963543; called by muse, mutect2, varscan2
- GATAD2A | c.1530C>T p.F510= | Silent (SNP) | VAF 54/165 reads (33%) | catalogued as COSV53076143; called by muse, mutect2, varscan2
- GCM2 | c.978C>T p.F326= | Silent (SNP) | VAF 61/185 reads (33%) | catalogued as COSV65276578; called by muse, mutect2, varscan2
- GPC1 | c.1182C>T p.I394= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV50866401; called by muse, mutect2, varscan2
- GPR31 | c.69G>A p.L23= | Silent (SNP) | VAF 8/27 reads (30%) | catalogued as rs773002663, COSV64762031; called by muse, mutect2, varscan2
- GRAMD2B | c.1245G>A p.V415= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs1393008573, COSV53510211; called by muse, mutect2, varscan2
- GRIK5 | c.1506C>T p.I502= | Silent (SNP) | VAF 26/85 reads (31%) | catalogued as rs1568895472, COSV53476538; called by muse, mutect2, varscan2
- HDAC10 | c.306C>T p.C102= | Silent (SNP) | VAF 7/30 reads (23%) | catalogued as rs538020281, COSV53135854; called by muse, mutect2, varscan2
- HES4 | c.162C>T p.L54= | Silent (SNP) | VAF 21/144 reads (15%) | catalogued as COSV100515130, COSV59242962; called by muse, varscan2
- HSD17B3 | c.219C>G p.L73= | Silent (SNP) | VAF 9/45 reads (20%) | catalogued as COSV64558421; called by muse, mutect2, varscan2
- HSPA12A | c.504C>T p.I168= | Silent (SNP) | VAF 31/179 reads (17%) | catalogued as COSV65023938; called by muse, mutect2, varscan2
- INSR | c.456C>G p.L152= | Silent (SNP) | VAF 41/113 reads (36%) | catalogued as COSV57173296; called by muse, mutect2, varscan2
- ITGB4 | c.3093C>A p.G1031= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV99564827; called by muse, mutect2
- KIF2C | c.1794G>A p.Q598= | Silent (SNP) | VAF 48/88 reads (55%) | catalogued as COSV64765687; called by muse, mutect2, varscan2
- KMT2C | c.4020C>T p.S1340= | Silent (SNP) | VAF 31/138 reads (22%) | catalogued as rs760642800, COSV51502118; called by muse, mutect2, varscan2
- KRTAP10-1 | c.705C>T p.L235= | Silent (SNP) | VAF 36/118 reads (31%) | catalogued as COSV59980206; called by muse, mutect2, varscan2
- LILRB1 | c.342G>A p.V114= (on ENST00000427581; = p.V78= on NM_006669.6) | Silent (SNP) | VAF 38/256 reads (15%) | catalogued as COSV61121744; called by muse, mutect2, varscan2
- LIPC | c.162C>T p.L54= | Silent (SNP) | VAF 58/272 reads (21%) | catalogued as COSV54427256; called by muse, mutect2, varscan2
- LRFN1 | c.618C>T p.F206= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as rs779116549, COSV50505873; called by muse, mutect2, varscan2
- LRRC34 | c.1394G>A p.*465= (on ENST00000446859 / NM_001172779.2; = p.*433= on NM_153353.5) | Silent (SNP) | VAF 25/94 reads (27%) | catalogued as COSV100336453; called by muse, mutect2, varscan2
- LRRK2 | c.1197G>A p.R399= | Silent (SNP) | VAF 9/62 reads (15%) | catalogued as COSV54170727; called by muse, mutect2, varscan2
- MAD2L2 | c.213C>G p.V71= | Silent (SNP) | VAF 36/96 reads (38%) | catalogued as COSV52419055; called by muse, mutect2, varscan2
- MDN1 | c.15819C>T p.I5273= | Silent (SNP) | VAF 61/133 reads (46%) | catalogued as COSV65530286; called by muse, mutect2, varscan2
- MEPCE | c.559C>T p.L187= | Silent (SNP) | VAF 17/121 reads (14%) | catalogued as rs1326453854, COSV52769206; called by muse, mutect2, varscan2
- MOV10 | c.513C>G p.L171= | Silent (SNP) | VAF 28/129 reads (22%) | catalogued as rs71659369, COSV62492716; called by muse, mutect2, varscan2
- MYADM | c.363C>T p.P121= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV61240986; called by muse, mutect2, varscan2
- MYH13 | c.5816G>A p.*1939= | Silent (SNP) | VAF 37/75 reads (49%) | catalogued as COSV52832404; called by muse, mutect2, varscan2
- MYO18B | c.5355C>T p.L1785= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs1232881998, COSV100125298; called by muse, mutect2
- MYO7A | c.1356C>G p.L452= | Silent (SNP) | VAF 5/63 reads (8%) | catalogued as COSV101289273; called by muse, mutect2
- NAV1 | c.2523C>T p.F841= | Silent (SNP) | VAF 75/210 reads (36%) | catalogued as COSV55226517; called by muse, varscan2
- NCKAP1L | c.3168C>G p.L1056= | Silent (SNP) | VAF 11/57 reads (19%) | catalogued as COSV53212397; called by muse, mutect2, varscan2
- NRF1 | c.1422G>A p.Q474= | Silent (SNP) | VAF 24/61 reads (39%) | catalogued as COSV56215114; called by muse, mutect2, varscan2
- NUP153 | c.4278C>A p.A1426= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV50465704; called by muse, mutect2, varscan2
- NUP188 | c.4209G>C p.L1403= | Silent (SNP) | VAF 30/68 reads (44%) | catalogued as COSV65341170; called by muse, mutect2, varscan2
- NUP188 | c.4311G>A p.V1437= | Silent (SNP) | VAF 55/107 reads (51%) | catalogued as rs1564568667, COSV65331929; called by muse, mutect2, varscan2
- NUP54 | c.585C>T p.F195= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV53577403; called by muse, mutect2, varscan2
- OBSCN | c.16428G>A p.E5476= | Silent (SNP) | VAF 24/60 reads (40%) | catalogued as COSV52830002; called by muse, mutect2, varscan2
- OR11H1 | c.648C>G p.L216= | Silent (SNP) | VAF 53/227 reads (23%) | catalogued as rs750663426, COSV53272644, COSV99421836, COSV99421945; called by muse, mutect2, varscan2
- OR1L1 | c.285C>T p.I95= (on ENST00000373686; = p.I45= on NM_001005236.3) | Silent (SNP) | VAF 48/97 reads (49%) | catalogued as COSV58936489; called by muse, mutect2, varscan2
- OR2V2 | c.192C>T p.L64= | Silent (SNP) | VAF 50/248 reads (20%) | catalogued as COSV60316517; called by muse, mutect2, varscan2
- OR5L1 | c.189C>T p.L63= | Silent (SNP) | VAF 221/463 reads (48%) | catalogued as rs1272160448, COSV61735431; called by muse, mutect2, varscan2
- PARD3B | c.1359C>T p.L453= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV62530806; called by muse, mutect2, varscan2
- PARP9 | c.1779C>A p.L593= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as COSV64451514; called by muse, mutect2, varscan2
- PAX2 | c.555C>T p.Y185= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs762289848, COSV62293077; called by muse, mutect2, varscan2
- PCDH15 | c.5238C>A p.P1746= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV57395128; called by mutect2, varscan2
- PCDHB7 | c.756C>T p.P252= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV50760031; called by muse, mutect2, varscan2
- PCDHGA5 | c.1668C>T p.N556= | Silent (SNP) | VAF 77/299 reads (26%) | catalogued as rs374639173; called by muse, mutect2, varscan2
- PCNX3 | c.4440C>T p.L1480= | Silent (SNP) | VAF 7/63 reads (11%) | catalogued as rs1355202535, COSV63140867; called by muse, mutect2, varscan2
- PCSK2 | c.1689C>T p.D563= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as rs375983990; called by muse, mutect2, varscan2
- PEX6 | c.627G>C p.R209= | Silent (SNP) | VAF 6/31 reads (19%) | catalogued as COSV55105519; called by muse, mutect2, varscan2
- PFAS | c.2418C>T p.L806= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV58983247; called by muse, mutect2, varscan2
- PKHD1L1 | c.2106G>A p.Q702= | Silent (SNP) | VAF 6/73 reads (8%) | catalogued as COSV65741623, COSV65753297; called by muse, mutect2
- PLXNB2 | c.4671C>T p.I1557= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs571623009, COSV63784591; called by muse, varscan2
- POLRMT | c.1863G>T p.L621= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as COSV52118881; called by muse, mutect2, varscan2
- PRKG2 | c.1887C>T p.F629= | Silent (SNP) | VAF 18/69 reads (26%) | catalogued as rs777632869, COSV52319108, COSV52332045; called by muse, mutect2, varscan2
- PYGB | c.192C>T p.L64= | Silent (SNP) | VAF 13/23 reads (57%) | catalogued as rs751691357, COSV53820419, COSV99404912; called by muse, mutect2, varscan2
- R3HDM1 | c.3198G>A p.Q1066= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as rs777250046, COSV51532846; called by muse, mutect2, varscan2
- RASAL3 | c.1449G>A p.L483= | Silent (SNP) | VAF 18/44 reads (41%) | catalogued as COSV59141766; called by muse, mutect2, varscan2
- RASGRF2 | c.2220G>C p.V740= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV54140000; called by muse, mutect2, varscan2
- RBM27 | c.2676G>A p.V892= | Silent (SNP) | VAF 9/56 reads (16%) | catalogued as COSV54594735; called by muse, mutect2, varscan2
- RIT2 | c.537G>A p.R179= | Silent (SNP) | VAF 27/112 reads (24%) | catalogued as rs983274355, COSV58677320; called by muse, mutect2, varscan2
- RNF126 | c.393C>T p.L131= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99443390; called by muse, varscan2
- RNF157 | c.252G>A p.L84= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs761215279, COSV53948334; called by muse, mutect2, varscan2
- RPL7A | c.198G>A p.Q66= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV100034868; called by muse, mutect2, varscan2
- RRP1B | c.1308G>T p.L436= | Silent (SNP) | VAF 3/31 reads (10%) | catalogued as COSV61478520; called by mutect2, varscan2
- SAMD9 | c.2901G>C p.L967= | Silent (SNP) | VAF 42/162 reads (26%) | catalogued as COSV66077521; called by muse, mutect2, varscan2
- SEMA4G | c.1398C>T p.H466= | Silent (SNP) | VAF 36/126 reads (29%) | catalogued as COSV52972221; called by muse, mutect2, varscan2
- SIAE | c.999C>T p.D333= | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs371229601; called by muse, mutect2, varscan2
- SLC4A4 | c.483G>A p.L161= (on ENST00000264485 / NM_001098484.3; = p.L117= on NM_003759.4) | Silent (SNP) | VAF 101/190 reads (53%) | catalogued as COSV52638220; called by muse, mutect2, varscan2
- SLFNL1 | c.147C>G p.L49= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV57235722; called by muse, mutect2, varscan2
- SMYD5 | c.54C>T p.R18= | Silent (SNP) | VAF 54/224 reads (24%) | catalogued as COSV50265738; called by mutect2, varscan2
- SOX9 | c.1137G>T p.A379= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as COSV99818776; called by muse, mutect2, varscan2
- SP140 | c.1080C>T p.T360= | Silent (SNP) | VAF 32/89 reads (36%) | catalogued as rs767987990, COSV59451135, COSV59455118; called by muse, mutect2, varscan2
- ST6GALNAC3 | c.670C>T p.L224= | Silent (SNP) | VAF 30/160 reads (19%) | catalogued as COSV60350031; called by muse, mutect2, varscan2
- STK35 | c.693G>A p.K231= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs1158029964, COSV99853097; called by muse, mutect2, varscan2
- SYT11 | c.207C>T p.L69= | Silent (SNP) | VAF 42/89 reads (47%) | catalogued as COSV64175172, COSV64176124; called by muse, mutect2, varscan2
- SYT11 | c.1188G>A p.L396= | Silent (SNP) | VAF 100/244 reads (41%) | catalogued as COSV64176137; called by muse, mutect2, varscan2
- TCF23 | c.249G>A p.A83= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as rs146034019; called by muse, mutect2, varscan2
- TIGD6 | c.237T>C p.D79= | Silent (SNP) | VAF 64/346 reads (18%) | catalogued as COSV57061791; called by muse, mutect2, varscan2
- TNXB | c.5100C>T p.S1700= (on ENST00000647633; = p.S1453= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 39/82 reads (48%) | catalogued as rs745736688, COSV64480484; called by muse, mutect2, varscan2
- TRIM24 | c.1854T>C p.S618= (on ENST00000343526 / NM_015905.3; = p.S584= on NM_003852.4) | Silent (SNP) | VAF 59/182 reads (32%) | catalogued as COSV58978240; called by muse, mutect2, varscan2
- TRPC4 | c.597C>A p.I199= | Silent (SNP) | VAF 35/150 reads (23%) | catalogued as COSV59019091; called by muse, mutect2, varscan2
- TRPV4 | c.771C>T p.L257= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as rs778796999, COSV55685723; called by muse, mutect2, varscan2
- TTYH2 | c.1500C>A p.I500= | Silent (SNP) | VAF 26/134 reads (19%) | catalogued as COSV53913393; called by muse, mutect2, varscan2
- UBR4 | c.10008G>A p.L3336= | Silent (SNP) | VAF 14/75 reads (19%) | catalogued as COSV64399388; called by muse, mutect2, varscan2
- VSIG1 | c.183C>T p.F61= | Silent (SNP) | VAF 42/70 reads (60%) | catalogued as COSV54262331; called by muse, mutect2, varscan2
- WDR59 | c.1413G>A p.Q471= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV50944864; called by muse, mutect2, varscan2
- WDR59 | c.1167G>A p.Q389= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as COSV50944914; called by muse, mutect2, varscan2
- XIRP2 | c.7530A>G p.Q2510= (on ENST00000628543; = p.Q2685= on NM_152381.6) | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as rs1170628652, COSV54734505; called by muse, mutect2, varscan2
- ZNF285 | c.1311C>T p.F437= | Silent (SNP) | VAF 45/115 reads (39%) | catalogued as COSV58411280; called by muse, mutect2, varscan2
- ZNF33A | c.1629G>A p.Q543= (on ENST00000458705 / NM_006974.3; = p.Q544= on NM_006954.2) | Silent (SNP) | VAF 24/196 reads (12%) | catalogued as COSV56727828; called by muse, mutect2, varscan2
- ZNF415 | c.507C>T p.V169= | Silent (SNP) | VAF 26/172 reads (15%) | catalogued as COSV54705269; called by muse, mutect2, varscan2
- ZNF71 | c.687C>T p.L229= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV60150231; called by muse, mutect2, varscan2
- DST | c.4297-4050G>C | Intron (SNP) | VAF 38/185 reads (21%) | catalogued as COSV55040006; called by muse, mutect2, varscan2
- ETFB | c.58-97C>T | Intron (SNP) | VAF 8/47 reads (17%) | catalogued as rs978749081, COSV58537451; called by muse, mutect2, varscan2
- MACF1 | c.15832-10914G>A | Intron (SNP) | VAF 40/190 reads (21%) | catalogued as rs1322034262, COSV57144362; called by muse, mutect2, varscan2
- NBPF25P | n.1170C>T | RNA (SNP) | VAF 200/555 reads (36%) | called by muse, mutect2, varscan2
- OR52A4P | n.589G>A | RNA (SNP) | VAF 32/76 reads (42%) | called by muse, mutect2, varscan2
- POFUT1 | c.542+291G>A | Intron (SNP) | VAF 27/322 reads (8%) | catalogued as rs753615464, COSV65260501; called by muse, mutect2
- TBC1D12 | c.-1G>A | 5'UTR (SNP) | VAF 4/41 reads (10%) | catalogued as rs762145762, COSV56552290, COSV56558736; called by mutect2, varscan2
- TMPRSS3 | chr21:42396055 T>A | 5'Flank (SNP) | VAF 9/38 reads (24%) | catalogued as COSV52308045; called by muse, mutect2, varscan2
